Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3893, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3893-01A (Primary Tumor).

Diagnosis:

This is a moderately to poorly differentiated adenocarcinoma of the rectosigmoidal junction of histopathological differentiation grade G2 to 3, with ulceration of the inner tumor surface, with peritumorous chronic recurrent secondary inflammation with an acute inflammatory flare, with carcinomatous lymphangitis, with tumor infiltration of the parietal layers into the subserous fatty connective tissue, with a regional lymph node metastasis (1/14) and tumor-free overview slices from all other resection material portions described.

According to the section preparations available, the tumor spread of the rectosigmoidal carcinoma corresponds to a tumor stage of pT3, pN1 (1/14), MX, L1, R0.

Tumor classification:

ICDO-DA M8140/3, G2 to 3.

8+

Source: NCI Genomic Data Commons file 63d9e007-096f-4b12-a03b-0a8b6760cd76 (TCGA-AG-3893.AC9ADE90-0865-4B4D-9ECD-A8183EF0E152.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).